Somatic mutation profile of tumor specimen C3L-02409-03 (aliquot CPT0111810009) from CPTAC case C3L-02409, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.9 years (22,254 days).
Specimen C3L-02409-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 491842ab-ff9e-40cb-b58a-0659f621294a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02409-31 (Blood Derived Normal), aliquot CPT0112820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18a1305a-cea1-49d8-b8b2-4b89211b398f

The open-access MAF lists 286 somatic variants for this specimen: 183 protein-altering or splice-affecting, 71 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 71, Frame Shift Del 26, Intron 13, Frame Shift Ins 11, Nonsense Mutation 7, 5'UTR 6, Splice Site 6, RNA 5, 5'Flank 3, 3'UTR 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 82/112 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 124/419 reads (30%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 113/300 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHANK3 | c.3658del p.A1220Pfs*57 | Frame Shift Del (DEL) | VAF 96/262 reads (37%) | catalogued as rs762292772; ClinVar: pathogenic; called by mutect2, varscan2
- ACE | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 157/383 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV99326598; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2204G>A p.C735Y | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99648229; called by muse, mutect2, varscan2
- AGBL3 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as rs1171188152; called by muse, mutect2
- AKAP8L | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 118/341 reads (35%) | catalogued as rs532848259, COSV101275792; called by muse, mutect2, varscan2
- AL096814.1 | c.273del p.F92Sfs*? | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1562052034; called by pindel, varscan2
- AP3M2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748317550, COSV51527709; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- AUTS2 | c.3529G>A p.G1177R | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272659885; called by muse, varscan2
- BEND2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs868376547, COSV66221592; called by muse, mutect2, varscan2
- BICRAL | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs113238307; called by muse, mutect2, varscan2
- C1orf127 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 12/371 reads (3%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); catalogued as rs1168477434; called by muse, mutect2
- CACNA1I | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747858090; called by muse, mutect2
- CARHSP1 | c.158+1G>A p.X53_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as rs759244031; called by muse, mutect2, varscan2
- CAVIN2 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 93/248 reads (38%) | catalogued as COSV58424145; called by muse, mutect2, varscan2
- CCDC81 | c.1816C>T p.R606W (on ENST00000445632 / NM_001156474.2; = p.R516W on NM_021827.4) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138508969; called by muse, mutect2, varscan2
- CFAP58 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as rs764839849; called by muse, mutect2, varscan2
- CHST8 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.234); catalogued as rs769054617, COSV52860575; called by muse, mutect2, varscan2
- CLCN7 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs923808258; called by muse, mutect2, varscan2
- CNTN4 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs780506289; called by muse, mutect2, varscan2
- CNTNAP1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1028647207, COSV52852659; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 49/111 reads (44%) | catalogued as rs748995811; called by mutect2, varscan2
- CPNE6 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs766215303; called by muse, mutect2, varscan2
- CSPG4 | c.4576dup p.A1526Gfs*5 | Frame Shift Ins (INS) | VAF 136/426 reads (32%) | catalogued as rs770045405; called by mutect2, pindel, varscan2
- DGKI | c.2750G>T p.R917L | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.042); catalogued as COSV55947529; called by muse, mutect2, varscan2
- DNAH5 | c.12929G>T p.S4310I | Missense Mutation (SNP) | VAF 35/551 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV54241753; called by muse, mutect2
- DNAI1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434548322, COSV54281149; called by muse, mutect2
- DOC2A | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757458777, COSV100451141, COSV58750916; called by muse, mutect2, varscan2
- EFEMP2 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs749794461; called by muse, mutect2
- F2R | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs546007149; called by muse, mutect2
- FBRSL1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); catalogued as rs894331393; called by muse, mutect2, varscan2
- FLG | c.6128A>G p.Q2043R | Missense Mutation (SNP) | VAF 179/1342 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as rs749111717, COSV64242957; called by muse, mutect2, varscan2
- FREM2 | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 109/305 reads (36%) | catalogued as rs371448296, COSV99748987; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as COSV54945907; called by mutect2, varscan2
- HMGCR | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs982576013; called by muse, mutect2, varscan2
- HOXD4 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 140/407 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60461247; called by muse, mutect2, varscan2
- ICE1 | c.4526G>A p.R1509H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs749575254, COSV99663307; called by muse, mutect2, varscan2
- IGSF21 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs200305863, COSV52136122; called by muse, mutect2, varscan2
- IL17RA | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 127/360 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771298130; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- KDM8 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200613161, COSV99619922; called by muse, mutect2, varscan2
- KIAA1958 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 130/384 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.227); catalogued as rs758153469, COSV61725806; called by muse, mutect2, varscan2
- KIF7 | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747632760, COSV51544087; called by muse, mutect2, varscan2
- KMT2B | c.7945C>T p.R2649C | Missense Mutation (SNP) | VAF 152/390 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99494975; called by muse, varscan2
- KMT2B | c.7946G>A p.R2649H | Missense Mutation (SNP) | VAF 136/402 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53073765; called by muse, mutect2, varscan2
- LONP1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs201021316; called by muse, mutect2, varscan2
- LRRC66 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751669990, COSV58633914, COSV58637046; called by muse, mutect2, varscan2
- MAB21L1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs771150876, COSV59769415; called by muse, mutect2, varscan2
- MACF1 | c.13798A>G p.M4600V (on ENST00000372915; = p.M2533V on NM_012090.5) | Missense Mutation (SNP) | VAF 13/399 reads (3%) | catalogued as COSV57116242; called by muse, mutect2
- MAPK15 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs372002074; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs750092100; called by mutect2, varscan2
- METTL14 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs748869746; called by muse, mutect2, varscan2
- MRPL39 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs766266905, COSV56260689; called by muse, mutect2
- MTMR10 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1406692786; called by muse, mutect2, varscan2
- MYO7A | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1555064199; called by muse, mutect2
- NEDD9 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1380661067; called by muse, mutect2, varscan2
- NEIL3 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs1560904763; called by muse, mutect2
- NIBAN3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1219411135; called by muse, mutect2
- NIPAL3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs375916946; called by muse, mutect2, varscan2
- OR6A2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200095225; called by muse, mutect2, varscan2
- P3H3 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370202438; called by muse, mutect2, varscan2
- PAQR8 | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1445770116; called by muse, mutect2
- PEG10 | c.517C>T p.R173C (on ENST00000482108 / NM_001040152.2; = p.R207C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV71788097; called by muse, mutect2, varscan2
- PGD | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs773136740; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PITPNM3 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs377404024; called by muse, mutect2, varscan2
- PMS1 | c.1567del p.S523Vfs*6 | Frame Shift Del (DEL) | VAF 28/127 reads (22%) | catalogued as rs1176438524; called by mutect2, pindel, varscan2
- PTGFR | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as rs780246149, COSV66116145; called by muse, mutect2, varscan2
- PTPRD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61927786; called by muse, mutect2
- RAB41 | c.162C>A p.N54K (on ENST00000374473 / NM_001363807.1; = p.N53K on NM_001032726.3) | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV52104785; called by muse, mutect2, varscan2
- RBL2 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.373); catalogued as rs761697149, COSV100044251; called by muse, mutect2, varscan2
- RBMXL3 | c.1394G>A p.C465Y | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1237451952; called by muse, varscan2
- ROBO3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 132/395 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs369787392; called by muse, mutect2, varscan2
- ROS1 | c.1226G>C p.S409T | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63861544; called by muse, mutect2, varscan2
- RPL13A | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 133/321 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs758542152; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 71/182 reads (39%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAGA | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65844130; called by muse, mutect2, varscan2
- RRN3 | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as rs780550932; called by muse, mutect2
- SALL3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs761436675; called by muse, mutect2, varscan2
- SGSM1 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs771440265, COSV68508640; called by muse, mutect2, varscan2
- SLC4A3 | c.392del p.G131Efs*139 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs760599959; called by mutect2, pindel, varscan2
- SPTA1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201568233, CM961351, COSV63752994; called by muse, mutect2, varscan2
- SPTBN2 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs769277232, COSV59452579; called by muse, mutect2, varscan2
- SS18L1 | c.916+1del | Frame Shift Del (DEL) | VAF 45/169 reads (27%) | catalogued as rs1204381214; called by mutect2, pindel, varscan2
- TCF19 | c.72dup p.A25Rfs*17 | Frame Shift Ins (INS) | VAF 114/324 reads (35%) | catalogued as rs751224053; called by mutect2, varscan2
- TIAM2 | c.4544C>T p.S1515L (on ENST00000529824; = p.S1486L on NM_012454.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs766878832, COSV51638757; called by muse, mutect2
- TMC2 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs749890793, COSV62651886; called by muse, mutect2, varscan2
- TMEM17 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs150163358; called by muse, mutect2, varscan2
- TNC | c.5014G>A p.E1672K | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs1357968241, COSV60789434; called by muse, mutect2, varscan2
- TSPOAP1 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 137/350 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs1413205236; called by muse, mutect2, varscan2
- TTC17 | c.2239_2241del p.S747del | In Frame Del (DEL) | VAF 24/85 reads (28%) | catalogued as rs773013435; called by pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs763254614; called by mutect2, varscan2
- UBTD2 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs746153347, COSV67143758; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs1359178990; called by muse, mutect2, varscan2
- XK | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66120808; called by muse, mutect2
- ZNF503 | c.1300A>G p.S434G | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as rs1300094001; called by muse, mutect2, varscan2
- ZNF618 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.381); catalogued as rs1358629363, COSV55930727; called by muse, mutect2
- ZSCAN5A | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs768639394, COSV54223645; called by muse, mutect2, varscan2
- AAK1 | c.1235del p.L412* | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- ACOT7 | c.222del p.T75Pfs*3 (on ENST00000377855 / NM_181864.3; = p.T65Pfs*3 on NM_007274.4) | Frame Shift Del (DEL) | VAF 129/368 reads (35%) | called by mutect2, pindel, varscan2
- AMER3 | c.547del p.S183Afs*83 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- AMPH | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO10 | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ANOS1 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 154/405 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP35 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARHGDIG | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ARHGEF2 | c.2489C>T p.T830I (on ENST00000361247 / NM_001162383.2; = p.T802I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2
- ARID1A | c.1793del p.P598Lfs*21 | Frame Shift Del (DEL) | VAF 38/107 reads (36%) | called by mutect2, pindel, varscan2
- BCORL1 | c.2309dup p.S771Qfs*6 | Frame Shift Ins (INS) | VAF 58/181 reads (32%) | called by mutect2, pindel, varscan2
- C4orf54 | c.4307G>T p.R1436L | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CCDC191 | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CNTLN | c.4085G>T p.W1362L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2B | c.916+1G>A p.X306_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- DNHD1 | c.7460G>A p.S2487N | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSP | c.7444G>A p.A2482T | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GALC | c.1503del p.F501Lfs*52 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- HAPLN3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 156/341 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HIRA | c.655-2A>G p.X219_splice | Splice Site (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- HORMAD1 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HSH2D | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ITGA9 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 131/554 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KCND3 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 126/388 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KIF13B | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIR2DL3 | c.820+1del p.X274_splice | Splice Site (DEL) | VAF 84/300 reads (28%) | called by mutect2, pindel, varscan2
- LHX9 | c.53del p.P18Qfs*76 | Frame Shift Del (DEL) | VAF 143/781 reads (18%) | called by mutect2, pindel, varscan2
- LMAN1L | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC24 | c.69_74del p.C23_A25delins* | Nonsense Mutation (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- LYST | c.1480T>C p.S494P | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGI2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MINDY4 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- MUC20 | c.1997G>T p.R666L | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUS81 | c.1194dup p.V399Cfs*8 | Frame Shift Ins (INS) | VAF 20/211 reads (9%) | called by mutect2, pindel
- MXRA5 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- MYO1B | c.3338G>A p.G1113E (on ENST00000304164; = p.G1055E on NM_012223.5) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NBAS | c.905T>C p.L302S | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2
- NCKAP1 | c.3240T>G p.N1080K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NCKAP1 | c.1573dup p.M525Nfs*22 | Frame Shift Ins (INS) | VAF 39/124 reads (31%) | called by mutect2, pindel, varscan2
- NFKB2 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1AP | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 105/590 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRDE2 | c.2123_2124del p.E708Gfs*32 | Frame Shift Del (DEL) | VAF 104/375 reads (28%) | called by pindel, varscan2
- NRXN2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR6C6 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR6K3 | c.817A>G p.M273V (on ENST00000368146; = p.M257V on NM_001005327.2) | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- OSBPL6 | c.1741A>G p.K581E | Missense Mutation (SNP) | VAF 153/448 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PARP15 | c.1647C>A p.D549E (on ENST00000464300 / NM_001113523.3; = p.D315E on NM_152615.2) | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PBRM1 | c.4477G>A p.G1493S (on ENST00000296302 / NM_001366071.2; = p.G1386S on NM_018313.5) | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDHA7 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 177/458 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PDGFRA | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.09); called by muse, mutect2
- PLXNA2 | c.92del p.P31Qfs*23 | Frame Shift Del (DEL) | VAF 84/533 reads (16%) | called by mutect2, pindel, varscan2
- POU3F4 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PPCS | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2
- PTPRT | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RAB20 | c.217del p.A73Rfs*10 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- RGS13 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- RYR3 | c.11461-2_11461-1insT p.X3821_splice (on ENST00000389232; = p.X3822_splice on NM_001036.6) | Splice Site (INS) | VAF 42/132 reads (32%) | called by mutect2, pindel, varscan2
- SCN5A | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD1B | c.2078dup p.P694Tfs*148 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- SHANK3 | c.3712G>A p.A1238T | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SND1 | c.1780-1G>T p.X594_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- STUB1 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- TAF10 | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF9B | c.166dup p.I56Nfs*7 | Frame Shift Ins (INS) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- TCHH | c.5126del p.F1709Sfs*42 | Frame Shift Del (DEL) | VAF 107/735 reads (15%) | called by mutect2, pindel, varscan2
- TCN1 | c.492dup p.E165Rfs*9 | Frame Shift Ins (INS) | VAF 95/351 reads (27%) | called by mutect2, pindel, varscan2
- TRPM6 | c.4798A>G p.N1600D | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2
- TRPS1 | c.3782A>C p.H1261P (on ENST00000220888 / NM_001330599.2; = p.H1274P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBLCP1 | c.269dup p.D91* | Frame Shift Ins (INS) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- UCHL5 | c.396T>A p.N132K | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UNC80 | c.8531G>A p.R2844Q | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- USP24 | c.2244_2247del p.D748Efs*38 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | called by pindel, varscan2
- USPL1 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2
- VRK1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZADH2 | c.129dup p.N44Qfs*32 | Frame Shift Ins (INS) | VAF 125/448 reads (28%) | called by mutect2, pindel, varscan2
- ZBED6 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZBTB32 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ZNF425 | c.2135A>G p.H712R | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ADAD1 | c.1263C>T p.C421= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1713C>T p.S571= | Silent (SNP) | VAF 63/199 reads (32%) | called by muse, mutect2, varscan2
- AGL | c.1884T>C p.N628= | Silent (SNP) | VAF 120/302 reads (40%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.1557A>G p.E519= | Silent (SNP) | VAF 112/317 reads (35%) | called by muse, mutect2, varscan2
- APCS | c.483C>T p.G161= | Silent (SNP) | VAF 43/271 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.1068T>C p.I356= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs758421133; called by muse, mutect2, varscan2
- BPIFB4 | c.714C>T p.S238= | Silent (SNP) | VAF 30/284 reads (11%) | catalogued as rs140769900; called by muse, mutect2, varscan2
- CABP4 | c.681G>A p.T227= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs1158715589; called by muse, mutect2
- CACNA1I | c.1509C>T p.S503= | Silent (SNP) | VAF 86/303 reads (28%) | called by muse, mutect2, varscan2
- CERCAM | c.702A>G p.P234= | Silent (SNP) | VAF 30/430 reads (7%) | catalogued as rs761194603; called by muse, mutect2
- CGNL1 | c.3123G>A p.T1041= | Silent (SNP) | VAF 110/298 reads (37%) | catalogued as rs760200854; called by muse, mutect2, varscan2
- CHST13 | c.408C>T p.R136= | Silent (SNP) | VAF 121/322 reads (38%) | catalogued as rs1448432219, COSV60041522; called by muse, mutect2, varscan2
- DHCR24 | c.1503C>T p.D501= | Silent (SNP) | VAF 152/393 reads (39%) | catalogued as rs575966588; called by muse, mutect2, varscan2
- DLGAP2 | c.1086C>T p.D362= | Silent (SNP) | VAF 121/356 reads (34%) | catalogued as rs758718171, COSV70099024; called by muse, mutect2, varscan2
- DOCK1 | c.1644G>A p.E548= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV99732024; called by muse, mutect2, varscan2
- DYNC2H1 | c.12609A>G p.S4203= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs377621045; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYSF | c.1614C>A p.P538= | Silent (SNP) | VAF 31/420 reads (7%) | catalogued as rs180970066, COSV99246902; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- EIF2AK4 | c.4452C>T p.D1484= | Silent (SNP) | VAF 45/237 reads (19%) | called by muse, mutect2, varscan2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 20/203 reads (10%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2
- GART | c.534A>G p.K178= | Silent (SNP) | VAF 56/145 reads (39%) | called by muse, mutect2, varscan2
- GLUD2 | c.33G>A p.P11= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV60152791; called by muse, mutect2, varscan2
- GPRIN1 | c.2688G>A p.A896= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs369418636; called by muse, mutect2, varscan2
- GRAP | c.546C>T p.G182= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs780578017; called by muse, mutect2, varscan2
- HAGH | c.804C>G p.T268= | Silent (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- HGF | c.936C>T p.G312= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs773660386, COSV55951716; called by muse, mutect2, varscan2
- HID1 | c.2109G>A p.V703= | Silent (SNP) | VAF 11/261 reads (4%) | catalogued as rs1188847525; called by muse, mutect2
- IFI44L | c.1203T>G p.V401= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs577528905; called by muse, mutect2, varscan2
- IGHV1-2 | c.228C>T p.G76= | Silent (SNP) | VAF 196/530 reads (37%) | catalogued as rs782657105; called by muse, mutect2, varscan2
- IL22 | c.213C>T p.D71= | Silent (SNP) | VAF 70/236 reads (30%) | called by muse, mutect2, varscan2
- IRF7 | c.936G>A p.T312= (on ENST00000397566; = p.T299= on NM_001572.5) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs750019396; called by muse, mutect2, varscan2
- KIF5B | c.1767T>C p.V589= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- LAMB1 | c.3423G>A p.T1141= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs757611151; called by muse, mutect2, varscan2
- LYST | c.10770A>G p.T3590= | Silent (SNP) | VAF 115/607 reads (19%) | called by muse, mutect2, varscan2
- MADD | c.51C>T p.I17= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs1409983548, COSV100211590; called by muse, mutect2, varscan2
- MAOA | c.54G>C p.V18= | Silent (SNP) | VAF 188/536 reads (35%) | called by muse, mutect2, varscan2
- MEAK7 | c.159C>T p.H53= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as rs185668209; called by muse, mutect2, varscan2
- MUC5AC | c.14124G>A p.Q4708= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs1275698892; called by muse, mutect2, varscan2
- NELFCD | c.1260G>A p.L420= (on ENST00000602795; = p.L402= on NM_198976.4) | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs1315579727; called by muse, mutect2
- NLRP2 | c.2016C>T p.D672= | Silent (SNP) | VAF 83/262 reads (32%) | catalogued as rs374613201; called by muse, mutect2, varscan2
- NPL | c.382C>T p.L128= | Silent (SNP) | VAF 28/760 reads (4%) | called by muse, mutect2
- NUMBL | c.291C>T p.H97= | Silent (SNP) | VAF 77/244 reads (32%) | catalogued as rs370977617, COSV53287296; called by muse, mutect2, varscan2
- NVL | c.2214C>T p.G738= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- OR2A14 | c.193C>T p.L65= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- PADI1 | c.1419G>A p.V473= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as rs1447844808, COSV64939115; called by muse, mutect2, varscan2
- PADI6 | c.459C>T p.S153= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs534938314; called by muse, mutect2, varscan2
- PCDHA5 | c.396C>T p.F132= | Silent (SNP) | VAF 94/258 reads (36%) | called by muse, mutect2, varscan2
- PHF21A | c.2010A>T p.T670= (on ENST00000418153 / NM_001101802.3; = p.T624= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- PNPLA2 | c.1080C>T p.P360= | Silent (SNP) | VAF 226/640 reads (35%) | catalogued as rs1299041723; called by muse, mutect2, varscan2
- PRDM15 | c.774G>A p.S258= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as rs555288106; called by muse, mutect2, varscan2
- PRIMA1 | c.87C>T p.F29= | Silent (SNP) | VAF 26/603 reads (4%) | called by muse, mutect2
- PTPRF | c.1953C>T p.G651= | Silent (SNP) | VAF 98/235 reads (42%) | catalogued as rs767436630; called by muse, mutect2, varscan2
- RAI1 | c.2289C>T p.G763= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as rs373122014; called by muse, mutect2
- RANBP2 | c.3279T>A p.I1093= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- RBMXL3 | c.456G>A p.P152= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs1197432343, COSV57751228; called by muse, mutect2, varscan2
- RPH3A | c.534G>A p.Q178= (on ENST00000389385 / NM_001143854.2; = p.Q174= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/189 reads (42%) | called by muse, mutect2, varscan2
- SAC3D1 | c.483C>A p.G161= | Silent (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- SEMA3B | c.1617C>T p.V539= | Silent (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1569G>A p.A523= | Silent (SNP) | VAF 71/217 reads (33%) | catalogued as rs774231245, COSV65646112, COSV65647330; called by muse, mutect2, varscan2
- SMARCA4 | c.2994C>T p.C998= | Silent (SNP) | VAF 203/583 reads (35%) | catalogued as rs1028929208, COSV60812717; ClinVar: likely benign; called by muse, mutect2, varscan2
- STK26 | c.12G>A p.S4= | Silent (SNP) | VAF 123/369 reads (33%) | called by muse, mutect2, varscan2
- SVIL | c.4302C>T p.N1434= (on ENST00000355867 / NM_021738.3; = p.N1008= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs867584549; called by muse, mutect2
- TMEM200C | c.564C>T p.H188= | Silent (SNP) | VAF 117/381 reads (31%) | catalogued as COSV67309996; called by muse, mutect2, varscan2
- TSPAN32 | c.633C>T p.S211= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs553461987; called by muse, mutect2, varscan2
- TSSK6 | c.336G>A p.A112= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs762459823, COSV53062749; called by muse, mutect2, varscan2
- TTC14 | c.475T>C p.L159= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- TUT1 | c.2463A>G p.E821= | Silent (SNP) | VAF 49/182 reads (27%) | called by muse, mutect2, varscan2
- VCP | c.1947T>C p.D649= | Silent (SNP) | VAF 21/204 reads (10%) | called by muse, mutect2, varscan2
- VPS13B | c.3654C>T p.C1218= | Silent (SNP) | VAF 76/237 reads (32%) | catalogued as rs200422365; called by muse, mutect2, varscan2
- ZBED1 | c.1905G>A p.R635= | Silent (SNP) | VAF 60/161 reads (37%) | called by muse, mutect2, varscan2
- ZIC3 | c.564G>A p.L188= | Silent (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- ZNF234 | c.1035G>A p.K345= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs752020022; called by muse, mutect2, varscan2
- AC009093.9 | n.587T>C | RNA (SNP) | VAF 27/114 reads (24%) | catalogued as rs761601207; called by muse, mutect2, varscan2
- AC243919.1 | n.318C>T | RNA (SNP) | VAF 99/331 reads (30%) | called by muse, mutect2, varscan2
- ADAM1A | n.1894C>G | RNA (SNP) | VAF 96/240 reads (40%) | called by muse, mutect2, varscan2
- AFG3L2 | c.628-11dup | Intron (INS) | VAF 53/151 reads (35%) | called by mutect2, varscan2
- CAMK2A | c.-7C>T | 5'UTR (SNP) | VAF 12/120 reads (10%) | catalogued as rs558645371, COSV62246110; called by muse, mutect2
- CAPS | c.-62_-61del | 5'UTR (DEL) | VAF 104/375 reads (28%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2461+2701G>A | Intron (SNP) | VAF 121/317 reads (38%) | catalogued as rs745706017, COSV56010288; called by muse, mutect2, varscan2
- COMMD3 | c.412-21G>A | Intron (SNP) | VAF 39/99 reads (39%) | catalogued as rs906206163; called by muse, mutect2, varscan2
- CYHR1 | c.246+67G>A | Intron (SNP) | VAF 24/270 reads (9%) | catalogued as rs1283390412, COSV100023935; called by muse, mutect2
- DNAI2 | c.1347+153A>G | Intron (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- DRP2 | c.-17del | 5'UTR (DEL) | VAF 106/266 reads (40%) | catalogued as rs754033940, COSV100872029; called by mutect2, varscan2
- EIF2AK1 | c.411+15del | Intron (DEL) | VAF 41/145 reads (28%) | called by mutect2, pindel, varscan2
- FAM104B | c.20+183C>T | Intron (SNP) | VAF 98/442 reads (22%) | catalogued as rs1209909524; called by muse, mutect2, varscan2
- FUNDC2P2 | n.221C>T | RNA (SNP) | VAF 106/226 reads (47%) | catalogued as rs780612092; called by muse, mutect2, varscan2
- HAPLN3 | c.-20G>A | 5'UTR (SNP) | VAF 167/441 reads (38%) | called by muse, mutect2, varscan2
- KDM6A | c.-36del | 5'UTR (DEL) | VAF 79/251 reads (31%) | catalogued as rs756752068; called by mutect2, pindel, varscan2
- LARP7 | c.1142+405G>A | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as rs746814799; called by muse, mutect2, varscan2
- LINGO3 | c.-43C>T | 5'UTR (SNP) | VAF 10/128 reads (8%) | catalogued as rs1413770838; called by muse, mutect2
- LRPAP1 | chr4:3500330 C>A | 3'Flank (SNP) | VAF 107/295 reads (36%) | called by muse, mutect2, varscan2
- MIA2 | c.1356+13G>A | Intron (SNP) | VAF 13/29 reads (45%) | catalogued as rs374042229; called by muse, varscan2
- NANOGNB | c.*51G>A | 3'UTR (SNP) | VAF 16/50 reads (32%) | catalogued as rs1293229165; called by muse, mutect2, varscan2
- PCDHA5 | c.2352+77del | Intron (DEL) | VAF 18/69 reads (26%) | catalogued as rs781996539; called by mutect2, pindel, varscan2
- PI4KA | c.*4G>T | 3'UTR (SNP) | VAF 152/462 reads (33%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9155034 T>C | 5'Flank (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2, varscan2
- QPRT | chr16:29679125 del C | 5'Flank (DEL) | VAF 48/142 reads (34%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34158814 G>A | 5'Flank (SNP) | VAF 43/140 reads (31%) | catalogued as rs756684681; called by muse, mutect2, varscan2
- SLC7A10 | c.789-48C>T | Intron (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- SSPOP | n.11904C>T | RNA (SNP) | VAF 77/164 reads (47%) | catalogued as rs1313091102; called by muse, mutect2, varscan2
- STIM1 | c.1541+2181A>G | Intron (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- TSHZ2 | c.41-67864dup | Intron (INS) | VAF 48/104 reads (46%) | called by mutect2, varscan2
- UBQLN2 | c.*26dup | 3'UTR (INS) | VAF 46/180 reads (26%) | catalogued as rs745344524; called by mutect2, varscan2
- USP19 | chr3:49108389 del C | 3'Flank (DEL) | VAF 5/36 reads (14%) | catalogued as rs1217191878; called by mutect2, pindel
